Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A3SN, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A3SN-01A (Primary Tumor).

[page 1 of 5]
Gender: Male

DOB:

Race:

Report Date:

Pathology Report:

ICD-O-3

Carcinoma, urothelial, NOS

8120/3

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Right pelvic lymph nodes:

- Twelve lymph nodes, no tumor (0/12).

B. Left pelvic lymph nodes:

- Fifteen lymph nodes, no tumor (0/15)

C. Bladder/prostate; cystoprostatectomy:

- Invasive urothelial carcinoma, see parameters.

- Residual high-grade in-situ carcinoma.

- Ulcerated urothelial mucosa with necrosis and granulomatous reaction

consistent with

treatment effect.

- One lymph node, no tumor (0/1)

- Prostatic adenocarcinoma, see parameters.

D. Distal left ureter:

- Ureter, no tumor.

E. Distal right ureter:

- Ureter, no tumor.

Site:

path: bladder, NOS

C67.9

CQCF: bladder, trigone

C67.0

4-9-12 RD

Urothelial Carcinoma Pathologic Parameters

1. Tumor type:

Papillary urothelial carcinoma, in-situ, adjacent to invasive lesion (see xxxxxxxxxxxx)

2. Grade of tumor:

High grade

3. Depth of invasion:

Extravesicular fat

4. Tumor distribution:

Solitary, 3.5 x 2.5 x 1.7 cm

Trigone

Posterior wall

5. Ureteral margins:

[page 2 of 5]
Negative

6. Distal urethral margin:

Negative

7. Soft tissue margin or serosa:

Negative

8. Lymph nodes:

Negative - zero out of twenty-eight (0/28)

9. pTNM:

pT3b, N0, MX

Prostate Pathologic Parameters

1. Gleason Score: 3+3=6

2. Perineural Invasion: Absent

3. Tumor Location:

Peripheral zone - Right

4. Tumor Volume Estimate: < 1%

5. High-grade P.I.N.: Multifocal

6. Seminal Vesicles: Negative for tumor

7. Extraprostatic extension: Absent

8. Peripheral Margin: Negative for tumor

9. Distal (apical) Margin: Negative for tumor

10. Proximal (basilar) Margin: Negative for tumor

11. Regional Lymph Nodes (right and left): Negative (0/28)

12. pTNM: pT2a, N0, MX

Effective . , this Checklist utilizes the edition TNM staging system for prostatectomy of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xxx

[] M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], M.D.

Electronically Signed Out by [], M.D.

Clinical History:

The patient is an year-old male with invasive high-grade papillary urothelial carcinoma cystoprostatectomy and

Specimens Received:

A: Right pelvic lymph nodes

B: Left pelvic lymph nodes

[page 3 of 5]
C: Bladder/prostate
D: Distal left ureter
E: Distal right ureter

Gross Description:

The specimens are received in five containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "right pelvic lymph nodes". Received fresh in place in formalin is a 6 x 3.2 x 1.1 cm aggregate of yellow to tan, lobulated adipose tissue the specimen is dissected for lymph node candidates 13 are ranging in size from 0.2-4.5 cm in greatest dimension and are submitted entirely as follows:

A1: 4 lymph node candidates
A2: 3 lymph node candidates
A3: 2 lymph node candidates
A4: 3 lymph node candidates
A5-A6: 1 lymph node candidate, sectioned

B. The second container is additionally identified as, "left pelvic lymph nodes". Received fresh in place in formalin is a 65 4 x 1.5 cm aggregate of yellow to tan, lobulated adipose tissue. The specimen is dissected for lymph node candidates and 20 are from ranging in size from 0.2-3 cm in greatest dimension and are submitted entirely as follows:

B1: 6 lymph node candidates
B2: 4 lymph node candidates
B3: 4 lymph node candidates
B4: 4 lymph node candidates
B5: 1 lymph node candidate, sectioned
B6: 1 lymph node candidate, sectioned

C. The third container is additionally identified as, "Bladder/prostate". Received fresh and placed in formalin is a 19 x 10.5 x 4 cm cystoprostatectomy specimen consisting of a 7.5 x 6.5 x 3 cm bladder with attached mesenteric fat and a 4.6 x 3.4 x 3.2 cm prostate. The right seminal vesicles measure 2.5 x 1.2 x 0.5 cm and right vas deferens measures 4.5 x 0.2 cm. The left seminal vesicles measures 2.5 x 1.3 x 0.2 cm and left vas deferens measures 3.9 x 0.2 cm. The right ureteral stump measures 0.4 cm in length by 0.2 cm in diameter, the left measures 0.8 cm in length by 0.2 cm in diameter, and both demonstrate intact, patent lumens.

The right half of the prostate is inked blue and the left half is inked black and the remaining outer surface is inked black. The bladder and prostate are opened anteriorly along the urethra. The prostate is surrounded by a thin,

[page 4 of 5]
intact membranous capsule and sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity with no discrete masses or indurations.

The opened bladder reveals a 3.5 x 2.5 cm white-tan, firm ulcerated mass with a rim of slightly raised red hemorrhagic tissue located in posterior-inferior wall (trigone area). On cut section, the mass extends through the bladder serosa into the perivesicular soft tissue to a depth of 1.7 cm and 0.1 cm the inked outer surface. The surrounding bladder mucosa is edematous and wrinkled with a uniform 1.1 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are involved by tumor and stenosed.

Representative sections are submitted as follows:

- C1: Distal prostatic urethral margin (apex)
- C2: Right ureter resection margin
- C3: Left ureter resection margin
- C4: Prostate apex
- C5: Lymph node candidate
- C6-C9: Representative right prostate
- C6: Below VT
- C7: At VT
- C8-C9: Base
- C10-C13: Representative left prostate
- C10: Below VT
- C11: At VT
- C12-C13: Base
- C14-C15: Sections of mass at transition from bladder to prostate (with SV and VD)
- C16-C17: Mass closest approach to inked outer surface
- C18-C19 : Mass involving perivesicular adipose tissue
- C20: Mass and adjacent uninvolved left lateral mucosa
- C21: Mass and adjacent uninvolved right lateral mucosa
- C22: Uninvolved bladder dome
- C23: Uninvolved anterior bladder

Gross photographs are taken.

D. The fourth container is additionally identified as, "distal left ureter stitch on non margin side". Received fresh and placed in formalin is a 2.2 cm long by 0.5 cm in diameter tube structure grossly consistent with ureter. There is a clear suture designating the non margin end. The margin is shaved and submitted en face as D1 and the remaining segment is submitted as D2.

E. The fifth container is additionally identified as, "distal right ureter stitch on non-margin side". Received fresh and placed in formalin is a 2.5 cm long by 0.5 cm in diameter tube structure grossly consistent with ureter there is a clear suture designating the non-margin end. The margin end is shaved and

[page 5 of 5]
submitted en face as E1 and the remaining segment is submitted as E2.

xxx

[], M.D.

Source: NCI Genomic Data Commons file 042fa888-e27a-4777-95aa-bb1ba15c3cda (TCGA-FD-A3SN.E204500A-A1F4-400C-A8C3-B830A832B719.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).